Gene-level copy-number profile of tumor specimen C3N-03225-01 from CPTAC case C3N-03225, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Age at diagnosis: 56.9 years (20,775 days).
Specimen C3N-03225-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 5403f45c-03bf-4d39-bf34-48b10e36e945.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-03225-71 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,716 have no estimate.
https://portal.gdc.cancer.gov/files/ca1a76b7-79e8-4343-9f63-0e23119e4673

Most common (modal) total copy number across autosomal genes: 1 — below the diploid value of 2.
Genes by total copy number (all chromosomes): copy number 0: 69; copy number 1: 27,592; copy number 2: 21,538; copy number 3: 6,869; copy number 4: 2,695; copy number 5: 144.

Homozygous deletions (total copy number 0; autosomes only): 69 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:113,325,372–113,436,042, 3 genes: AC016745.1, IGKV1OR2-108, AC016745.2.
- chr8:36,378,069–37,625,873, 17 genes (within-gene range 0–1): AC090809.1, RPL23P10, RNA5SP264, KCNU1, AC124076.1, TPT1P8, AC090453.1, AC092818.1, SMARCE1P4, AC091182.1, AC091182.2, LINC01605, AC124067.1, AC124067.2, AC124067.3, AC124067.4, AC137579.2.
- chr9:21,367,424–25,089,151, 49 genes: IFNA13, IFNA2, AL353732.1, IFNA11P, IFNA12P, IFNA8, AL353732.2, IFNWP2, IFNA1, MIR31HG, IFNWP19, IFNE, MIR31, SNORD39, H3P30, KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1, LINC01239, AL391117.1, CLIC4P1, AC017067.1, AL445623.2, SUMO2P2, AL445623.1, NOP56P2, ELAVL2, AL365204.1, AL365204.2, AL365204.3, IZUMO3, AL353811.1, RMRPP5, RN7SKP120.

Amplified relative to the modal value (total copy number ≥ 3, i.e. more than twice the modal value of 1; autosomes only): 9,707 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:32,600,172–45,688,113, 396 genes, copy number 3 (within-gene range 1–3) (broad region; genes not listed).
- chr1:143,905,487–207,879,115, 1,659 genes, copy number 3 (within-gene range 1–3) (broad region; genes not listed).
- chr4:46,243,548–46,244,215, 1 gene, copy number 3: AC104072.1.
- chr4:48,341,529–49,062,081, 12 genes, copy number 3: SLAIN2, SLC10A4, ZAR1, FRYL, RNU5E-3P, OCIAD1, OCIAD1-AS1, OCIAD2, RNU6-158P, AC020593.1, CWH43, TPI1P4.
- chr4:51,843,000–63,529,761, 157 genes, copy number 3 (broad region; genes not listed).
- chr5:58,198–181,342,213, 2,901 genes, copy number 3 (broad region; genes not listed).
- chr8:73,064,543–145,066,685, 1,102 genes, copy number 4 (broad region; genes not listed).
- chr11:106,674,019–113,475,691, 134 genes, copy number 3 (broad region; genes not listed).
- chr12:55,684,568–99,984,654, 774 genes, copy number 3 (within-gene range 2–3) (broad region; genes not listed).
- chr14:18,333,726–50,105,043, 804 genes, copy number 3–4 (broad region; genes not listed).
- chr16:11,555–62,357,746, 1,767 genes, copy number 3–5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 24,739. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
